Somatic mutation profile of tumor specimen 0DZRYP from CCDI case PBCTTS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Retinoblastoma, diffuse; Tissue or organ of origin: Eye, NOS; Age at diagnosis: 6.3 years (2,290 days).
Specimen 0DZRYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68ff9707-29a6-4c3f-9028-5f85e55b64c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZRYU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392db9d9-215d-4e4f-8dd6-d1a5b0ecf846

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Splice Site 2, 3'UTR 2, 5'UTR 2, RNA 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 378/497 reads (76%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFAP44 | c.4700T>C p.V1567A | Missense Mutation (SNP) | VAF 134/749 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.154); catalogued as rs756427990; called by muse, mutect2, varscan2
- HRNR | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.703); catalogued as rs761620569; called by muse, mutect2, varscan2
- PARVB | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 120/327 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1345336192; called by muse, varscan2
- PTTG1IP | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 29/487 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1433045193; called by muse, mutect2
- SNX9 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 131/555 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.543); catalogued as rs760959192; called by muse, mutect2, varscan2
- BCOR | c.3456dup p.P1153Afs*15 | Frame Shift Ins (INS) | VAF 42/106 reads (40%) | called by mutect2, varscan2
- BCOR | c.1679_1682del p.S560Cfs*28 | Frame Shift Del (DEL) | VAF 32/114 reads (28%) | called by mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 22/802 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- METTL4 | c.439G>T p.A147S | Missense Mutation (SNP) | VAF 45/779 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2
- NRXN1 | c.3547-1G>C p.X1183_splice | Splice Site (SNP) | VAF 118/599 reads (20%) | called by muse, mutect2, varscan2
- RMND5B | c.1024C>A p.R342S | Missense Mutation (SNP) | VAF 40/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOB | c.1341C>T p.H447= | Silent (SNP) | VAF 57/299 reads (19%) | catalogued as rs370418745; called by muse, mutect2, varscan2
- GPR152 | c.153G>A p.A51= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs113329646, COSV56886227; called by muse, mutect2, varscan2
- MYRIP | c.837A>C p.A279= | Silent (SNP) | VAF 103/374 reads (28%) | catalogued as rs371804523; called by muse, mutect2, varscan2
- CCNDBP1 | c.-57G>T | 5'UTR (SNP) | VAF 3/17 reads (18%) | called by muse, varscan2
- LINC02694 | n.551T>C | RNA (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- NADK2 | c.*1447A>G | 3'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs976618275; called by muse, mutect2
- NRBP2 | c.-55G>A | 5'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- PPP6R1 | c.-6-56C>T | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- SOGA1 | c.*73G>T | 3'UTR (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2, varscan2
